Surgical pathology report (de-identified scan), TCGA case TCGA-24-1434, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1434-01A (Primary Tumor).

[page 1 of 4]
Other Related Clinical Data:

DIAGNOSIS: OVARIES, RIGHT AND LEFT, BILATERAL SALPINGI-OOPHORECTOMY

- PAPILLARY SEROUS ADENOCARCINOMA
- DIFFUSE LYMPHVASCULAR SPACE INVASION IDENTIFIED
- SEE COMMENT AND SYNOPSIS

FALLOPIAN TUBE, SIDE NOT SPECIFIED, BILATERAL SALPINGO-OOPHORECTOMY

- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA
- DIFFUSE LYMPHVASCULAR SPACE INVASION IDENTIFIED

UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY

- DIFFUSE LYMPHVASCULAR SPACE INVASION BY PAPILLARY SEROUS ADENOCARCINOMA
- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA IN PARACERVICAL SOFT TISSUE

UTERUS, ENDOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- INACTIVE
- ENDOMETRIAL POLYP

UTERUS, MYOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY

- DIFFUSE LYMPHVASCULAR SPACE INVASION BY PAPILLARY SEROUS ADENOCARCINOMA

UTERUS, SEROSAL SURFACE, TOTAL ABDOMINAL HYSTERECTOMY

- EXTENSIVE METASTATIC PAPILLARY SEROUS ADENOCARCINOMA

[page 2 of 4]
Patient Name:

DOB:

SOFT TISSUE, ANTERIOR CUL-DE-SAC, BIOPSY
- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA

OMENTUM, EXCISION
- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

Intraoperative Consultation:

FS: Tumor, anterior cul-de-sac, biopsy
- "Adenocarcinoma, consistent with Mullerian origin," by

Microscopic Description and Comment: Sections of both ovaries show extensive poorly differentiated papillary serous adenocarcinoma. The tumor has a high nuclear grade, a well developed papillary architecture in many areas, and is associated with numerous psammoma bodies. The tumor effaces large areas of the ovaries and is present on the ovarian surfaces, and extends into the paratubal soft tissue. Of note, foci of in situ papillary serous adenocarcinoma are noted in the tubal epithelium. Diffuse lymphovascular space invasion in the adnexa is also noted. Extensive sectioning of the additional fragments of tissue received with the TAH/BSO specimen show large fragments of soft tissue entirely effaced by tumor. One fallopian tube is not identified in the multiple sections submitted.

Sections of the uterus show diffuse serosal metastasis by papillary serous carcinoma. In addition, there is extensive lymphovascular space permeation by tumor in the myometrium, lower uterine segment, and cervix, and in some areas the foci of intravascular tumor are invading into the immediately adjacent stroma. In addition, extensive metastatic adenocarcinoma is present in the paracervical soft tissue. The endometrium is inactive, and an endometrial polyp is identified as an incidental finding.

Sections of the anterior cul-de-sac biopsy show metastatic papillary serous carcinoma. Similarly, sections of the omentum show almost complete effacement by metastatic papillary serous adenocarcinoma.

History: The patient is a with a pelvic mass and malignant ascites.
Operative procedure: Exploratory laparotomy, total abdominal hysterectomy, bilateral salpingo-oophorectomy. Clinical diagnosis: Pelvic mass, malignant ascites.

Specimen(s) Received:

A: TUMOR ANTERIOR CULDESAC
B: HYSTERECTOMY, BSO
C: OMENTUM, ROUTINE

Gross Description The specimens are received in three containers of formalin, each labeled with the patient's name. The container is additionally labeled "tumor anterior cul-de-sac." It contains a white cassette. Labeled FS1. Tissue remaining from frozen section labeled A1. Also in this container are four pieces of pink-tan tissue ranging in size from 1.2 cm in greatest dimension to 3.2 cm in greatest dimension. Two sections submitted in one cassette labeled A2. Jar 1.

[page 3 of 4]
Patient Name: [REDACTED]

DOB: [REDACTED]

The second container is labeled "uterus, tubes, and ovaries." It contains greater than 20 pieces of tissue ranging in size from 0.2 cm in greatest dimension to 8 x 6 x 3.0 cm. The largest piece of tissue is grossly identifiable as a uterus. The serosal surface of the uterus is not identifiable and the uterus is encased in a combination of dense fibrous tissue, and possibly tumor. The uterus is unable to be oriented. A small, 0.6 cm in greatest dimension, endometrial polyp is present. Also identifiable is one set of adnexa measuring 7.5 x 6.0 x 3.5 cm. A 7.5 x 5.5 x 2.5 cm cystic space is present. This cystic space has been previously opened, and contains friable dark brown material with focal papillary areas. The serosal surface is partially identifiable, and large amounts of tumor is present on the serosal surface. A portion of partial fallopian tube is identified measuring 4.5 cm in length. On cut section, the lumen is patent. The remainder of the tissues present in the container consist of solid, tan masses of tumor with fibrous tissue and focal adipose tissue. Labeled B1 - section of cervix; B2 - lower uterine segment; B3 - endometrium myometrium; B4 - cervix from opposite side; B5

- lower uterine segment from opposite side; B6 - opposite side endometrium myometrium; B7 - fallopian tube; B8 - solid area tumor adjacent to cystic structure; B9 - sections of cyst wall, along with surface tumor; B10 - papillary area within cyst; B11 - representative sections of solid tumor infiltrating fat from loose fragments of tissue. B12 - B14 - sections of second adnexa. Jar 2.

The third container is labeled "omentum." It contains a 20 x 5 x 4 cm piece of omentum, which is essentially completely replaced by tumor. One section of tumor labeled C1. Jar 2.

Synopsis SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS 1. A neoplasm is PRESENT 2. The HISTOLOGIC DIAGNOSIS is Serous papillary adenocarcinoma 3. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are: Right and left ovary (synchronous primary tumors) 4. AND 5. The NUCLEAR (BRODERS') GRADE of the tumor is: G3 (Poorly-differentiated) 6. Tumor IS identified on the ovarian surface(s). 7 Tumor DOES invade the mesovarium. 8. Tumor DOES invade the adjacent fallopian tube. 9. Tumor DOES invade the pelvic soft tissue. 10. Tumor involvement of the pelvic peritoneum is PRESENT. 11. Metastatic involvement of the EXTRAPELVIC peritoneum CANNOT BE EVALUATED. 12. Metastatic involvement of the omentum is PRESENT. 13. The maximum dimension of tumor implants outside the true pelvis is greater than 4 cm . 14. Metastatic involvement of the uterine serosa is PRESENT. 15. Metastatic involvement of the endometrium is ABSENT. 16. Regional lymph node metastases CANNOT BE EVALUATED. 17. The total number of regional lymph nodes examined is 0. 18. The total number of metastatically-involved regional lymph nodes cannot be determined. 19. DETAILED STAGING INFORMATION:

Based on the above information, the PRIMARY TUMOR is classified as:

TNM Scheme	FIGO Scheme	Definition	Macroscopic
T3c	IIIC	peritoneal metastasis beyond true pelvis measuring > 2 cm in	

greatest dimension

THE REGIONAL LYMPH NODES are classified as: NX (Nodal status cannot be assessed)

THE STATUS OF DISTANT TUMOR SITES is classified as: MX (Status cannot be assessed) 20. The FINAL AJCC/UICC/FIGO STAGE IS: AJCC/UICC/FIGO IIIC (T3c/NX/MX)

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Amendments

[page 4 of 4]
Patient Name: .

DOB:

Reason: The report was amended to correct a typographical error.

Source: NCI Genomic Data Commons file 4828060e-545e-4ce3-b0a3-4724d4de6a08 (TCGA-24-1434.0A5FD2A4-560B-4769-BA4E-868854471961.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).